Surgical pathology report (de-identified scan), TCGA case TCGA-76-6657, project TCGA-GBM (Glioblastoma Multiforme), tissue source site Thomas Jefferson University, specimen TCGA-76-6657-01A (Primary Tumor).

[page 1 of 3]
Patient: [REDACTED]

Accessioned: [REDACTED]

[REDACTED] TCGA-76-6657

SURGICAL PATHOLOGY REPORT

FINAL DIAGNOSIS:

1. SPECIMEN DESIGNATED "Left temporal malignant glioma":
GLIOBLASTOMA, WHO GRADE iv. SEE MICROSCOPIC DESCRIPTION.
2. SPECIMEN DESIGNATED "Left temporal glioblastoma":
GLIOBLASTOMA,
WHO GRADE IV.

[REDACTED]
Report Electronically Signed on [REDACTED]

This diagnostic report has been personally interpreted by the signatory of record.

Microscopic Description:

The tumor is composed of pleomorphic neoplastic glial cells. Mitotic figures are identified in tumor cells. Tumor necrosis and endothelial proliferation are also identified. Tumor cells show positive immunohistochemical staining for GFAP. Scattered tumor cell nuclei show positive immunohistochemical staining for p53.

Frozen Section Diagnosis:

1. Left temporal malignant glioma: Glioblastoma. Frozen section diagnosis by [REDACTED]

[page 2 of 3]
[REDACTED]

Clinical History and Diagnosis:

Left temporal malignant glioma

Source of Specimen:

1: Left temporal malignant glioma

2: Left temporal glioblastoma

Gross Description:

[REDACTED]

1. Left temporal malignant glioma: Received fresh for frozen section in the specimen container labeled with patient's name and "#1 left temporal malignant glioma" is a 2.5 x 1.5 x 0.6 cm aggregate of tan-white soft tissue. Touch prep is done. 50% of the specimen is submitted for frozen section. The specimen is submitted as follows:

A FSC

B. the remainder of the specimen

2. Left temporal glioblastoma: Received in formalin in the specimen container labeled with patient's name and "#2 left temporal glioblastoma" is a 2 x 2 x 0.8 cm aggregate of tan-red soft tissue. The specimen is entirely submitted in 2 cassettes.

Histology Laboratory

H&E

Part 1: Left temporal malignant glioma

GLIAL FIBRILLARY ACIDIC PROTEIN (GFAP)

P 53

Immunohistochemistry Notes

1. Quantification of immunohistochemistry assay for ER and PR studies is by the method of Battiafora et.al. Applied Immunohistochemistry,
[REDACTED]

[page 3 of 3]
[REDACTED]

2. Hercept Test (DakoCytomation) Formalin fixed, paraffin embedded.
Interpretation follows the manufacturer' s recommendation.

Documented by [REDACTED]
[REDACTED]

EGFR pharmDx Clone 2-18C9 Formalin fixed, paraffin embedded.
Interpretation follows the manufacturer' s recommendation.

Docuemented by [REDACTED]
[REDACTED]

3. Analyte Specific Reagent (ASCR) Disclaimer. The use of one or more reagents in the above tests is regulated as an analyte specific reagent (ASR).

These tests were developed and their performance characteristics determined by the [REDACTED]
[REDACTED]

They have not been cleared by the US Food and Drug Administration. The FDA has determined that such clearance or approval is not necessary.

Source: NCI Genomic Data Commons file 34943199-a338-46c6-9514-9b37ca5dff94 (TCGA-76-6657.476EED15-94AF-4C24-9A4F-17FBDE281C66.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).